Somatic mutation profile of tumor specimen C3N-01489-02 (aliquot CPT0105940009) from CPTAC case C3N-01489, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 65.2 years (23,810 days).
Specimen C3N-01489-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d47608a2-1abc-4ccf-99e8-f44fcb9801e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01489-31 (Blood Derived Normal), aliquot CPT0108270002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9f834f6d-620c-475f-9e71-9709bfc7bc38

The open-access MAF lists 834 somatic variants for this specimen: 589 protein-altering or splice-affecting, 153 silent, 92 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 507, Silent 153, Intron 48, Nonsense Mutation 45, RNA 18, Splice Region 14, Frame Shift Del 13, Splice Site 10, 3'UTR 9, 5'Flank 7, 5'UTR 6, 3'Flank 4.

Variants (750 of 834; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 29/254 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RYR1 | c.7373G>T p.R2458L | Missense Mutation (SNP) | VAF 51/389 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs121918594, CM118674, CM981783, COSV62093719; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SACS | c.5151del p.K1717Nfs*8 | Frame Shift Del (DEL) | VAF 13/62 reads (21%) | catalogued as rs754439135, CD1515371; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- TP53 | c.314G>T p.G105V | Missense Mutation (SNP) | VAF 24/112 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs587781504, COSV52708806, COSV52766179, COSV52793434; ClinVar: likely pathogenic; called by muse, varscan2
- TP53 | c.313G>T p.G105C | Missense Mutation (SNP) | VAF 25/115 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM043949, COSV52726068, COSV52741717, COSV53015551; called by muse, varscan2
- ABCA13 | c.12664G>T p.A4222S | Missense Mutation (SNP) | VAF 51/158 reads (32%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.948); catalogued as rs199630218, COSV101291424; called by muse, mutect2, varscan2
- ABCC5 | c.1273G>T p.G425C | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55596033; called by muse, mutect2, varscan2
- AC098582.1 | c.777G>T p.K259N | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.03); catalogued as COSV99986141; called by muse, mutect2, varscan2
- ADAD2 | c.265del p.E89Nfs*59 (on ENST00000315906 / NM_001145400.2; = p.E89Nfs*65 on NM_139174.4) | Frame Shift Del (DEL) | VAF 13/101 reads (13%) | catalogued as rs777065536; called by mutect2, pindel
- ADAM33 | c.1545G>T p.W515C | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV100598061; called by muse, mutect2
- ADAMTS16 | c.2977G>T p.G993W | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56979014, COSV56985648; called by muse, mutect2, varscan2
- ADAMTS19 | c.421G>T p.G141C | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs1274834719; called by muse, mutect2
- ADCY5 | c.1861G>T p.E621* | Nonsense Mutation (SNP) | VAF 12/202 reads (6%) | catalogued as rs1553726627; called by muse, mutect2
- ADGRB2 | c.2047G>T p.D683Y | Missense Mutation (SNP) | VAF 21/284 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57070599; called by muse, mutect2
- ADGRG4 | c.6411C>A p.D2137E | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as COSV54966854; called by muse, mutect2, varscan2
- AGBL4 | c.883C>A p.P295T | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.733); catalogued as COSV61895296; called by muse, mutect2
- AGTR2 | c.851T>A p.M284K | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as rs782418793; called by muse, mutect2, varscan2
- AKR1B1 | c.924G>T p.K308N | Missense Mutation (SNP) | VAF 27/233 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as COSV99605400; called by muse, mutect2, varscan2
- ALK | c.1415G>A p.R472Q | Missense Mutation (SNP) | VAF 55/345 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.033); catalogued as COSV66560627; called by muse, mutect2, varscan2
- ANK2 | c.923G>T p.R308L | Missense Mutation (SNP) | VAF 10/279 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52152842; called by muse, mutect2
- ANKRD34C | c.802C>A p.R268S | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV104436223; called by muse, mutect2
- APOB | c.6333C>A p.Y2111* | Nonsense Mutation (SNP) | VAF 6/78 reads (8%) | catalogued as rs1351772223; called by muse, mutect2
- APOB | c.5515A>T p.I1839F | Missense Mutation (SNP) | VAF 26/311 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as rs750585092; called by muse, mutect2
- AURKC | c.341G>T p.R114L (on ENST00000302804 / NM_001015878.2; = p.R80L on NM_003160.3) | Missense Mutation (SNP) | VAF 55/460 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as rs1051922045, COSV57139850; called by muse, mutect2, varscan2
- BCOR | c.4120A>T p.R1374W (on ENST00000378444 / NM_001123385.2; = p.R1340W on NM_017745.6) | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60699928; called by muse, mutect2, varscan2
- BEST3 | c.1226G>C p.R409T | Missense Mutation (SNP) | VAF 11/173 reads (6%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV100437882; called by muse, mutect2
- BRSK1 | c.2029C>A p.P677T | Missense Mutation (SNP) | VAF 37/386 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.098); catalogued as COSV58670034; called by muse, mutect2
- BSN | c.8192G>T p.G2731V | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV56512538; called by muse, mutect2
- CACNA2D3 | c.2204C>A p.S735Y | Missense Mutation (SNP) | VAF 19/204 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.335); catalogued as COSV55586713; called by muse, mutect2
- CACNB1 | c.1474C>T p.R492W | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV59998707; called by muse, mutect2, varscan2
- CATSPERE | c.721G>T p.A241S | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs770945995; called by muse, mutect2, varscan2
- CFAP47 | c.1410+1G>A p.X470_splice | Splice Site (SNP) | VAF 19/49 reads (39%) | catalogued as COSV52881762; called by muse, mutect2
- CFAP61 | c.2408C>A p.T803K | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.706); catalogued as rs780255308, COSV55619741, COSV55624296; called by muse, mutect2, varscan2
- CLMN | c.1892C>T p.P631L | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV54184394; called by muse, mutect2
- COL22A1 | c.3508C>A p.Q1170K | Missense Mutation (SNP) | VAF 29/224 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57333317; called by muse, mutect2, varscan2
- COL3A1 | c.2243G>T p.G748V | Missense Mutation (SNP) | VAF 27/298 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV58584208; called by muse, mutect2
- CSMD3 | c.278G>T p.W93L | Missense Mutation (SNP) | VAF 26/276 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52145938, COSV99852544; called by muse, mutect2
- CTR9 | c.2135A>G p.Y712C | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.723); catalogued as rs991851483; called by muse, mutect2
- CYP2S1 | c.749G>T p.R250L | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as COSV59505219; called by muse, mutect2, varscan2
- DCLK2 | c.729G>T p.K243N | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV56212295; called by muse, mutect2, varscan2
- DHTKD1 | c.346G>T p.E116* | Nonsense Mutation (SNP) | VAF 31/208 reads (15%) | catalogued as COSV53804891; called by muse, varscan2
- DNMT1 | c.2994G>T p.E998D | Missense Mutation (SNP) | VAF 48/311 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.665); catalogued as rs745780816; called by muse, mutect2, varscan2
- EGFLAM | c.811G>C p.D271H | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as rs1382214144; called by muse, mutect2, varscan2
- ELK1 | c.1045G>T p.G349W | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1267720408; called by muse, mutect2, varscan2
- EMX2 | c.169G>T p.A57S | Missense Mutation (SNP) | VAF 28/249 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.028); catalogued as COSV101463615; called by muse, mutect2, varscan2
- EPHA3 | c.970+1G>A p.X324_splice | Splice Site (SNP) | VAF 11/88 reads (13%) | catalogued as rs754818412, COSV60692385, COSV60716695; called by muse, mutect2, varscan2
- FANCM | c.1439T>C p.M480T | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs776804525, COSV57496794; called by muse, mutect2
- FAT3 | c.5969C>T p.S1990L | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.674); catalogued as COSV53077188; called by muse, mutect2, varscan2
- FBXO30 | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 26/195 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.814); catalogued as COSV99395383; called by muse, mutect2, varscan2
- FCER1A | c.15G>T p.M5I | Missense Mutation (SNP) | VAF 22/186 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as COSV63667435; called by muse, mutect2, varscan2
- FCHO1 | c.861G>T p.K287N | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.479); catalogued as COSV53183032; called by muse, mutect2, varscan2
- FCN3 | c.779G>T p.R260L | Missense Mutation (SNP) | VAF 58/363 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV54642211, COSV54642253; called by muse, mutect2, varscan2
- FLG2 | c.476C>A p.S159Y | Missense Mutation (SNP) | VAF 25/224 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV101166176; called by muse, mutect2, varscan2
- FRMPD4 | c.3400C>A p.P1134T | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.014); catalogued as rs768838591; called by muse, mutect2, varscan2
- FSCN1 | c.1210C>A p.L404M | Missense Mutation (SNP) | VAF 40/183 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1160722911; called by muse, mutect2, varscan2
- GABRA2 | c.704-1G>T p.X235_splice | Splice Site (SNP) | VAF 24/96 reads (25%) | catalogued as COSV62915943; called by muse, mutect2
- GABRB3 | c.529C>A p.L177M | Missense Mutation (SNP) | VAF 30/403 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54664336; called by muse, mutect2
- GJA1 | c.917G>A p.S306N | Missense Mutation (SNP) | VAF 38/323 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99247351; called by muse, mutect2, varscan2
- GJB7 | c.238C>A p.Q80K | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs766833315; called by muse, mutect2
- GOLGA5 | c.1806G>C p.Q602H | Missense Mutation (SNP) | VAF 26/315 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50836293; called by muse, mutect2
- GP2 | c.160C>A p.P54T | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs759085734; called by muse, mutect2, varscan2
- GTSF1 | c.51C>A p.C17* | Nonsense Mutation (SNP) | VAF 20/213 reads (9%) | catalogued as rs924230935; called by muse, mutect2
- HAPLN4 | c.421T>C p.Y141H | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1568609087; called by muse, mutect2, varscan2
- HEPHL1 | c.995C>A p.T332K | Missense Mutation (SNP) | VAF 32/232 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs893566464; called by muse, mutect2, varscan2
- HOXC10 | c.424G>C p.E142Q | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV100329023; called by muse, mutect2
- HPD | c.491C>A p.A164E | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.044); catalogued as rs1391457977; called by muse, mutect2
- IGDCC3 | c.1513G>T p.G505W | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60078617; called by muse, mutect2
- IGLON5 | c.5C>G p.P2R | Missense Mutation (SNP) | VAF 11/73 reads (15%) | PolyPhen possibly damaging (0.804); catalogued as rs765466638; called by muse, mutect2, varscan2
- IGSF8 | c.1541G>A p.G514E | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV58758217; called by muse, mutect2, varscan2
- INTS5 | c.2903G>T p.R968L | Missense Mutation (SNP) | VAF 35/238 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV57952723; called by muse, mutect2, varscan2
- IQGAP1 | c.292C>T p.R98* | Nonsense Mutation (SNP) | VAF 7/125 reads (6%) | catalogued as COSV51590592; called by muse, mutect2
- ISLR2 | c.1876C>T p.R626C | Missense Mutation (SNP) | VAF 21/191 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1567164800; called by muse, mutect2, varscan2
- KATNIP | c.2426G>T p.R809L | Missense Mutation (SNP) | VAF 33/202 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as COSV55176926; called by muse, mutect2, varscan2
- KCNJ3 | c.368G>C p.C123S | Missense Mutation (SNP) | VAF 12/280 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54538278; called by muse, mutect2
- KSR1 | c.2754G>T p.L918F | Missense Mutation (SNP) | VAF 25/249 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.466); catalogued as rs1295532322; called by muse, mutect2
- LMBR1L | c.1083-4G>T | Splice Region (SNP) | VAF 17/125 reads (14%) | catalogued as rs1052735366, COSV57269450; called by muse, mutect2, varscan2
- LPO | c.2107G>T p.D703Y | Missense Mutation (SNP) | VAF 40/284 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs562677658, COSV99228718; called by muse, mutect2, varscan2
- MAP4K2 | c.367-5G>T | Splice Region (SNP) | VAF 19/143 reads (13%) | catalogued as rs369940309; called by muse, mutect2, varscan2
- MMEL1 | c.563C>A p.P188H | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1167126265; called by muse, mutect2
- MRO | c.685C>T p.Q229* | Nonsense Mutation (SNP) | VAF 8/106 reads (8%) | catalogued as COSV56496160; called by muse, mutect2
- MUC17 | c.4531G>A p.E1511K | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.246); catalogued as COSV60295164; called by muse, mutect2, varscan2
- MUC4 | c.3502C>A p.P1168T | Missense Mutation (SNP) | VAF 40/245 reads (16%) | SIFT tolerated, low confidence (0.4); PolyPhen probably damaging (0.935); catalogued as rs768193910; called by muse, mutect2, varscan2
- MYH2 | c.533C>A p.T178N | Missense Mutation (SNP) | VAF 47/316 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM145481, COSV55438798; called by muse, mutect2, varscan2
- MYT1 | c.682A>G p.T228A | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.01); catalogued as rs758740062; called by muse, mutect2, varscan2
- NCK2 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs755385208, COSV51895316; called by muse, mutect2, varscan2
- NDC1 | c.530G>T p.G177V | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52338367; called by muse, mutect2
- NID2 | c.367C>A p.L123M | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.365); catalogued as COSV99357324; called by muse, mutect2
- NOXO1 | c.745G>A p.E249K (on ENST00000397280 / NM_172168.3; = p.E243K on NM_144603.4) | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.102); catalogued as rs1264960922, COSV50191463; called by muse, mutect2
- NRXN1 | c.2314G>T p.D772Y | Missense Mutation (SNP) | VAF 31/216 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1176656152, COSV58476553; called by muse, mutect2, varscan2
- NTRK3 | c.1834C>A p.P612T | Missense Mutation (SNP) | VAF 31/261 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs373273419, COSV62315183; called by muse, mutect2, varscan2
- OAZ3 | c.265G>T p.E89* | Nonsense Mutation (SNP) | VAF 28/201 reads (14%) | catalogued as COSV58617861; called by muse, mutect2, varscan2
- OR10T2 | c.653C>A p.S218Y | Missense Mutation (SNP) | VAF 14/161 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57782693; called by muse, mutect2
- OR11H12 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as rs778510222, COSV101612483; called by muse, mutect2, varscan2
- OR1E2 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 12/191 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs1302913090; called by muse, mutect2
- OR2L13 | c.283G>T p.G95* | Nonsense Mutation (SNP) | VAF 28/349 reads (8%) | catalogued as rs771380572, COSV100813657, COSV63559079; called by muse, mutect2
- OR2T2 | c.61C>A p.H21N | Missense Mutation (SNP) | VAF 52/1000 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100737790; called by muse, mutect2
- OR4C3 | c.689G>T p.G230V | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.253); catalogued as COSV100168275; called by muse, mutect2, varscan2
- OR4P4 | c.132G>T p.M44I | Missense Mutation (SNP) | VAF 7/129 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0.009); catalogued as COSV58920777; called by muse, mutect2
- OR51E1 | c.425C>A p.P142H | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as COSV67810577; called by muse, mutect2, varscan2
- OR51M1 | c.124C>A p.P42T | Missense Mutation (SNP) | VAF 44/308 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV60785304; called by muse, mutect2, varscan2
- OR5M1 | c.315C>G p.I105M | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV73202247, COSV73202295; called by muse, mutect2, varscan2
- OR6P1 | c.754T>C p.Y252H | Missense Mutation (SNP) | VAF 42/512 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1194632949; called by muse, mutect2
- OTOG | c.4159G>A p.V1387M | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.277); catalogued as rs1007053235; called by muse, mutect2
- P2RY8 | c.1000C>A p.R334S | Missense Mutation (SNP) | VAF 20/189 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.859); catalogued as rs373565479; called by muse, mutect2, varscan2
- PAPPA | c.3301G>A p.V1101I | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60283249; called by muse, mutect2, varscan2
- PAX8 | c.1058G>A p.G353E | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54509272; called by muse, mutect2, varscan2
- PCDH11X | c.211G>C p.D71H | Missense Mutation (SNP) | VAF 45/217 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53461991; called by muse, mutect2, varscan2
- PCDHA12 | c.2161C>A p.L721M | Missense Mutation (SNP) | VAF 43/244 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.589); catalogued as rs1366996546; called by muse, mutect2, varscan2
- PCDHA13 | c.1748G>T p.R583L | Missense Mutation (SNP) | VAF 42/330 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.038); catalogued as rs143828814, COSV56481595; called by muse, mutect2, varscan2
- PCDHA3 | c.1542C>G p.S514R | Missense Mutation (SNP) | VAF 77/625 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV63539417; called by muse, mutect2, varscan2
- PCDHA7 | c.2023G>A p.A675T | Missense Mutation (SNP) | VAF 66/330 reads (20%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.009); catalogued as rs1554135925; called by muse, mutect2, varscan2
- PIK3C3 | c.1303A>G p.I435V | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1226414809; called by muse, mutect2, varscan2
- PKHD1 | c.6109C>T p.L2037F | Missense Mutation (SNP) | VAF 51/415 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61896631; called by muse, mutect2, varscan2
- PLEKHN1 | c.1891G>T p.G631C (on ENST00000379409; = p.G579C on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.928); catalogued as rs765491496, COSV58021580; called by muse, mutect2, varscan2
- PODN | c.1965G>T p.E655D (on ENST00000395871; = p.E607D on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV57016297; called by muse, mutect2, varscan2
- POLR2H | c.361C>G p.L121V | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV52615696; called by muse, mutect2
- POLRMT | c.2881G>T p.A961S | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.254); catalogued as COSV99242028; called by muse, mutect2, varscan2
- POM121L12 | c.485G>T p.G162V | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.281); catalogued as rs1380902160, COSV68692463; called by muse, mutect2, varscan2
- POM121L12 | c.557C>G p.P186R | Missense Mutation (SNP) | VAF 48/225 reads (21%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV101374983, COSV68692376; called by muse, mutect2, varscan2
- POU2AF1 | c.140C>A p.P47H | Missense Mutation (SNP) | VAF 34/261 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.754); catalogued as rs1412194786; called by mutect2, varscan2
- PPEF2 | c.1243G>T p.E415* | Nonsense Mutation (SNP) | VAF 16/88 reads (18%) | catalogued as COSV54420334, COSV54425422; called by mutect2, varscan2
- PTPRH | c.1763del p.P588Lfs*65 | Frame Shift Del (DEL) | VAF 19/168 reads (11%) | catalogued as COSV54746480; called by mutect2, varscan2
- PTPRT | c.3350G>T p.R1117L | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61967306; called by muse, mutect2
- PTPRT | c.1230C>A p.F410L | Missense Mutation (SNP) | VAF 26/288 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as COSV100628521; called by muse, mutect2
- RAD21 | c.454A>G p.I152V | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0.011); catalogued as rs897373910; called by muse, mutect2
- RAI14 | c.1079C>T p.T360I | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54298480, COSV99462861; called by muse, mutect2
- RBP3 | c.781G>C p.G261R | Missense Mutation (SNP) | VAF 27/258 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555211030; called by muse, mutect2
- RGS19 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV58658478; called by muse, mutect2
- RNF103 | c.1319G>T p.R440L | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0.253); catalogued as rs375282269, COSV52896627; called by muse, mutect2, varscan2
- RYR1 | c.872C>A p.A291E | Missense Mutation (SNP) | VAF 47/336 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as rs200572262, COSV62099630; called by muse, mutect2, varscan2
- SALL1 | c.632C>T p.S211F | Missense Mutation (SNP) | VAF 21/190 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1174750691, COSV51760113; called by muse, mutect2, varscan2
- SEMA6C | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.945); catalogued as rs767624194; called by muse, mutect2, varscan2
- SETD2 | c.4279G>T p.V1427F | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.823); catalogued as COSV57447104; called by muse, mutect2, varscan2
- SKI | c.1934G>A p.R645Q | Missense Mutation (SNP) | VAF 11/219 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as COSV66014326; called by muse, mutect2
- SLC10A2 | c.692C>G p.T231R | Missense Mutation (SNP) | VAF 32/311 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.396); catalogued as COSV55358384; called by muse, mutect2, varscan2
- SLC27A1 | c.388G>A p.V130M | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs550720711; called by muse, mutect2, varscan2
- SLC32A1 | c.876G>T p.W292C | Missense Mutation (SNP) | VAF 45/349 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54146790; called by muse, mutect2, varscan2
- SLC6A1 | c.1255C>G p.R419G | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV55117217; called by muse, mutect2
- SPEG | c.7286G>T p.W2429L | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1266400020; called by muse, mutect2, varscan2
- SPTA1 | c.5215C>A p.Q1739K | Missense Mutation (SNP) | VAF 58/363 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV99071274; called by muse, mutect2, varscan2
- SPTB | c.2160G>T p.E720D | Missense Mutation (SNP) | VAF 40/434 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV67631080; called by muse, mutect2
- SSBP4 | c.104A>G p.Q35R | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.189); catalogued as rs1286918400; called by muse, mutect2, varscan2
- STXBP5L | c.1864G>T p.G622* | Nonsense Mutation (SNP) | VAF 24/144 reads (17%) | catalogued as COSV56539766; called by muse, mutect2, varscan2
- TBX10 | c.356C>A p.P119H | Missense Mutation (SNP) | VAF 39/252 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56875887; called by muse, mutect2, varscan2
- TGIF2LX | c.92C>T p.S31L | Missense Mutation (SNP) | VAF 44/193 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); catalogued as rs749102763; called by muse, mutect2, varscan2
- THSD1 | c.1447G>T p.D483Y | Missense Mutation (SNP) | VAF 24/242 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV51626326; called by muse, mutect2
- TMPRSS4 | c.593A>T p.K198M | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as rs1565437757; called by muse, mutect2, varscan2
- TNFAIP3 | c.60G>C p.K20N | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as rs1302093455; called by muse, mutect2, varscan2
- TNS1 | c.2756G>T p.R919L | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as rs777917136, COSV50715934; called by mutect2, varscan2
- TRHDE | c.2201C>T p.P734L | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.31); catalogued as COSV99673066; called by muse, mutect2, varscan2
- TRPC3 | c.932C>G p.A311G (on ENST00000379645 / NM_001366479.2; = p.A238G on NM_003305.2) | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53373688; called by muse, mutect2
- TRPC7 | c.813G>T p.K271N | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV61458010; called by muse, mutect2, varscan2
- TSBP1 | c.1446A>T p.Q482H (on ENST00000617061; = p.Q487H on NM_006781.5) | Missense Mutation (SNP) | VAF 70/291 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66659535; called by muse, mutect2, varscan2
- TTLL10 | c.223G>C p.G75R (on ENST00000379289 / NM_001130045.2; = p.G2R on NM_153254.3) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.164); catalogued as COSV101016620; called by muse, mutect2
- UBAC2 | c.319G>T p.D107Y | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV100854202; called by muse, varscan2
- USP32 | c.4735G>A p.D1579N | Missense Mutation (SNP) | VAF 12/251 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.318); catalogued as rs1464026006; called by muse, mutect2
- USP40 | c.2476G>T p.G826* | Nonsense Mutation (SNP) | VAF 9/213 reads (4%) | catalogued as COSV99297294; called by muse, mutect2
- VEGFA | c.682G>T p.D228Y (on ENST00000523873 / NM_001171623.1; = p.D391Y on NM_003376.6) | Missense Mutation (SNP) | VAF 93/499 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100035240; called by muse, mutect2, varscan2
- WDR36 | c.998C>G p.S333C | Missense Mutation (SNP) | VAF 21/253 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.804); catalogued as rs770455424; called by muse, mutect2
- ZIC3 | c.1006G>A p.G336R | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1474420006, COSV54972474, COSV99799052; called by muse, mutect2, varscan2
- ZNF221 | c.769G>T p.G257W | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as rs1413023849; called by muse, mutect2, varscan2
- ZNF532 | c.326C>A p.S109Y | Missense Mutation (SNP) | VAF 21/260 reads (8%) | SIFT tolerated (0.84); PolyPhen benign (0.261); catalogued as COSV60173495; called by muse, mutect2
- ZNF780B | c.1409G>A p.G470E | Missense Mutation (SNP) | VAF 32/233 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775945014, COSV55467289; called by mutect2, varscan2
- ZSCAN5B | c.855del p.N286Tfs*6 | Frame Shift Del (DEL) | VAF 36/361 reads (10%) | catalogued as rs1181964280; called by mutect2, varscan2
- ZSWIM3 | c.1181G>T p.S394I | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54849711; called by muse, mutect2
- ABCA13 | c.14206G>T p.A4736S | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.676); called by muse, mutect2
- ABCA2 | c.2810A>G p.Y937C (on ENST00000614293; = p.Y907C on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCG8 | c.1880A>T p.D627V | Missense Mutation (SNP) | VAF 50/414 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- AC024940.1 | n.4341G>T | Splice Region (SNP) | VAF 19/191 reads (10%) | called by muse, mutect2
- ACAP1 | c.1089C>A p.F363L | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.056); called by muse, mutect2
- ACE | c.3341G>T p.G1114V | Missense Mutation (SNP) | VAF 63/472 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADCK1 | c.713A>T p.Q238L | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ADGRD2 | c.1380G>T p.W460C | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- AGT | c.893A>T p.Q298L | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- AK4 | c.469G>A p.V157I | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALDH4A1 | c.229G>T p.D77Y | Missense Mutation (SNP) | VAF 22/207 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- ALMS1 | c.4297G>T p.E1433* | Nonsense Mutation (SNP) | VAF 14/150 reads (9%) | called by muse, mutect2
- AMY2B | c.469A>G p.K157E | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT tolerated (0.76); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ANKRD35 | c.1984G>T p.A662S | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- ANKUB1 | c.855G>T p.K285N | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.247); called by muse, mutect2
- ANO4 | c.2703del p.I902Ffs*4 (on ENST00000392977 / NM_001286615.2; = p.I867Ffs*4 on NM_178826.4) | Frame Shift Del (DEL) | VAF 12/87 reads (14%) | called by mutect2, pindel, varscan2
- APOB | c.4773C>A p.F1591L | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- AQP9 | c.253C>A p.P85T | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); called by muse, mutect2
- ARFGEF2 | c.5182T>A p.F1728I | Missense Mutation (SNP) | VAF 23/244 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.132); called by muse, mutect2
- ARHGEF37 | c.53G>T p.R18M | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.02); called by muse, mutect2
- ARHGEF37 | c.1545C>A p.S515R | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- ARID1A | c.1525C>T p.P509S | Missense Mutation (SNP) | VAF 35/496 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2
- ARID1A | c.5546G>T p.G1849V | Missense Mutation (SNP) | VAF 27/204 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.1030G>T p.A344S | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.999); called by muse, mutect2
- ARRDC5 | c.979C>A p.Q327K (on ENST00000381781; = p.Q313K on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ASTL | c.555del p.M185Ifs*43 | Frame Shift Del (DEL) | VAF 14/121 reads (12%) | called by mutect2, pindel
- ASTN1 | c.191C>A p.P64H | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ATP1A3 | c.2272T>A p.F758I (on ENST00000545399 / NM_001256214.2; = p.F745I on NM_152296.5) | Missense Mutation (SNP) | VAF 32/277 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP1A4 | c.2995C>A p.P999T | Missense Mutation (SNP) | VAF 30/265 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP4A | c.349G>T p.V117F | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.859); called by muse, mutect2
- ATP9A | c.383A>G p.Y128C | Missense Mutation (SNP) | VAF 38/375 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- AZIN1 | c.155A>T p.H52L | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2
- B4GALNT4 | c.1031G>T p.C344F | Missense Mutation (SNP) | VAF 22/199 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- BAZ2B | c.2253T>A p.Y751* | Nonsense Mutation (SNP) | VAF 8/70 reads (11%) | called by muse, mutect2
- BCL9 | c.2920A>T p.T974S | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- BEND2 | c.2037G>T p.L679F | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- BMP15 | c.973C>A p.L325I | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2
- BMP7 | c.1034A>T p.Q345L | Missense Mutation (SNP) | VAF 53/512 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0.125); called by muse, mutect2
- BPIFA1 | c.433C>A p.L145M | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.357); called by muse, mutect2
- BRD8 | c.3422A>T p.K1141M | Missense Mutation (SNP) | VAF 32/207 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.485); called by muse, varscan2
- BTBD17 | c.140A>T p.Q47L | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BTNL8 | c.831G>T p.Q277H (on ENST00000340184 / NM_001040462.3; = p.G321C on NM_024850.2) | Missense Mutation (SNP) | VAF 16/169 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- C10orf53 | c.350G>T p.C117F | Missense Mutation (SNP) | VAF 36/344 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- C10orf71 | c.613A>C p.T205P | Missense Mutation (SNP) | VAF 34/208 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- C12orf40 | c.1460C>A p.P487Q | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- C1QTNF8 | c.302A>T p.Q101L | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- C20orf144 | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C4orf17 | c.280G>T p.V94L | Missense Mutation (SNP) | VAF 37/214 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- C9orf78 | c.688G>C p.E230Q | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); called by muse, varscan2
- CACNA1E | c.1594C>T p.P532S | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); called by muse, mutect2
- CACNG6 | c.316G>C p.A106P | Missense Mutation (SNP) | VAF 26/175 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- CARMIL2 | c.4070G>A p.G1357E | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- CARNMT1 | c.1126G>T p.E376* | Nonsense Mutation (SNP) | VAF 13/84 reads (15%) | called by muse, mutect2, varscan2
- CCDC168 | c.3864A>T p.K1288N | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.415); called by muse, mutect2
- CCN4 | c.106C>A p.P36T | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CCNB3 | c.2666A>G p.E889G | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- CD200R1 | c.320G>T p.W107L (on ENST00000471858 / NM_170780.3; = p.W130L on NM_138806.4) | Missense Mutation (SNP) | VAF 22/315 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CDHR2 | c.408C>A p.T136= | Splice Region (SNP) | VAF 33/149 reads (22%) | called by muse, mutect2, varscan2
- CEACAM7 | c.572G>T p.R191M | Missense Mutation (SNP) | VAF 28/304 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CEP97 | c.2267G>T p.G756V | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- CFAP46 | c.6030C>A p.D2010E | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- CFAP65 | c.4372C>A p.R1458S | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- CHAT | c.1632C>T p.Y544= | Splice Region (SNP) | VAF 35/338 reads (10%) | called by muse, mutect2, varscan2
- CHL1 | c.432G>T p.E144D | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.08); called by muse, mutect2
- CHRNB2 | c.837C>A p.F279L | Missense Mutation (SNP) | VAF 42/210 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHRNB3 | c.649G>C p.V217L | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- CIART | c.117G>T p.K39N | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); called by muse, mutect2
- CLIP2 | c.316G>T p.G106C | Missense Mutation (SNP) | VAF 36/400 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CLRN2 | c.514C>A p.Q172K | Missense Mutation (SNP) | VAF 42/282 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CNST | c.2113G>T p.D705Y | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL17A1 | c.2300G>T p.G767V | Missense Mutation (SNP) | VAF 42/442 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL28A1 | c.1328A>G p.Q443R | Missense Mutation (SNP) | VAF 14/221 reads (6%) | SIFT tolerated (0.78); PolyPhen benign (0.248); called by muse, mutect2
- COL4A1 | c.3733G>T p.G1245C | Missense Mutation (SNP) | VAF 33/215 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL6A5 | c.4811A>T p.Q1604L | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- CORIN | c.731G>A p.R244K | Missense Mutation (SNP) | VAF 22/215 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- CPD | c.593del p.G198Afs*65 | Frame Shift Del (DEL) | VAF 8/83 reads (10%) | called by mutect2, pindel, varscan2
- CPS1 | c.2504C>A p.S835Y | Missense Mutation (SNP) | VAF 36/382 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.547); called by muse, mutect2
- CRYGA | c.163C>A p.Q55K | Missense Mutation (SNP) | VAF 34/263 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSMD1 | c.713T>C p.I238T | Missense Mutation (SNP) | VAF 13/208 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.158); called by muse, mutect2
- CTSZ | c.242G>T p.R81L | Missense Mutation (SNP) | VAF 17/191 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.661); called by muse, mutect2
- DCAF4L2 | c.482C>A p.A161E | Missense Mutation (SNP) | VAF 47/243 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- DCLK1 | c.1141C>T p.Q381* | Nonsense Mutation (SNP) | VAF 17/128 reads (13%) | called by muse, mutect2, varscan2
- DDX3X | c.1807C>T p.Q603* (on ENST00000399959; = p.Q604* on NM_001356.5) | Nonsense Mutation (SNP) | VAF 18/72 reads (25%) | called by muse, mutect2, varscan2
- DDX4 | c.184G>T p.G62W | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- DDX56 | c.928G>T p.D310Y | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- DHX9 | c.160A>G p.K54E | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DMD | c.4015C>A p.L1339I | Missense Mutation (SNP) | VAF 31/176 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- DNA2 | c.852A>G p.I284M | Missense Mutation (SNP) | VAF 22/239 reads (9%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); called by muse, mutect2
- DNAH8 | c.3758C>A p.S1253Y | Missense Mutation (SNP) | VAF 55/258 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- DNAI2 | c.1314G>T p.M438I | Missense Mutation (SNP) | VAF 51/436 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- DOCK3 | c.2757G>T p.M919I | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- DSP | c.7547G>T p.R2516M | Missense Mutation (SNP) | VAF 73/369 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DST | c.21258G>T p.M7086I (on ENST00000361203 / NM_001374722.1; = p.M4783I on NM_015548.5) | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- DST | c.10021C>A p.L3341I | Missense Mutation (SNP) | VAF 17/176 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- DTX1 | c.743G>T p.R248L | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.141); called by muse, mutect2
- DYNC1H1 | c.7459G>T p.E2487* | Nonsense Mutation (SNP) | VAF 20/162 reads (12%) | called by muse, mutect2, varscan2
- DYNC2LI1 | c.149G>T p.R50M | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- EFTUD2 | c.2819G>T p.R940M | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EFTUD2 | c.1891G>T p.G631C | Missense Mutation (SNP) | VAF 39/251 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- EIF2AK2 | c.1003G>T p.E335* | Nonsense Mutation (SNP) | VAF 30/236 reads (13%) | called by muse, mutect2, varscan2
- EIPR1 | c.193G>T p.G65C | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ELMO1 | c.1906-7C>A | Splice Region (SNP) | VAF 10/125 reads (8%) | called by muse, mutect2
- EML4 | c.642-2A>T p.X214_splice | Splice Site (SNP) | VAF 8/96 reads (8%) | called by muse, mutect2
- EMX1 | c.535C>T p.Q179* | Nonsense Mutation (SNP) | VAF 34/366 reads (9%) | called by muse, mutect2
- ERAL1 | c.573G>T p.W191C | Missense Mutation (SNP) | VAF 34/283 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ERC2 | c.2191G>T p.E731* | Nonsense Mutation (SNP) | VAF 10/196 reads (5%) | called by muse, mutect2
- ESRP1 | c.541G>T p.V181F | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- EXD3 | c.1501G>T p.V501L | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAM135B | c.3184A>T p.T1062S | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM217B | c.733G>T p.G245C | Missense Mutation (SNP) | VAF 28/296 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.075); called by muse, mutect2
- FAM25C | c.113A>T p.H38L | Missense Mutation (SNP) | VAF 26/465 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); called by muse, mutect2
- FAM47B | c.59G>T p.W20L | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- FAM50B | c.68G>T p.R23M | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.028); called by muse, mutect2
- FAT3 | c.5968T>A p.S1990T | Missense Mutation (SNP) | VAF 19/181 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- FAT4 | c.3428A>T p.Q1143L | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- FBXO40 | c.828G>T p.Q276H | Missense Mutation (SNP) | VAF 38/220 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- FBXW7 | c.235G>T p.E79* | Nonsense Mutation (SNP) | VAF 21/177 reads (12%) | called by muse, mutect2, varscan2
- FCRL1 | c.622C>A p.P208T | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FGF13 | c.188-1G>T p.X63_splice | Splice Site (SNP) | VAF 5/29 reads (17%) | called by muse, mutect2, varscan2
- FHOD3 | c.4255G>A p.E1419K (on ENST00000359247 / NM_001281739.3; = p.E1436K on NM_025135.5) | Missense Mutation (SNP) | VAF 11/202 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2
- FLG | c.10918T>C p.S3640P | Missense Mutation (SNP) | VAF 62/519 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FLG | c.7529C>A p.S2510Y | Missense Mutation (SNP) | VAF 99/498 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- FNDC3B | c.62G>T p.G21V | Missense Mutation (SNP) | VAF 47/328 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
- FOXA1 | c.1267G>A p.A423T | Missense Mutation (SNP) | VAF 20/646 reads (3%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.836); called by muse, mutect2
- FOXC2 | c.1417G>T p.G473C | Missense Mutation (SNP) | VAF 56/399 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- GAB1 | c.1750G>T p.D584Y | Missense Mutation (SNP) | VAF 18/246 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- GABPA | c.1033G>C p.E345Q | Missense Mutation (SNP) | VAF 18/237 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); called by muse, mutect2
- GABRA2 | c.756T>A p.Y252* | Nonsense Mutation (SNP) | VAF 24/230 reads (10%) | called by muse, mutect2, varscan2
- GABRA4 | c.1308C>A p.F436L | Missense Mutation (SNP) | VAF 30/239 reads (13%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GAD2 | c.727G>T p.G243C | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GALNT13 | c.546G>T p.M182I | Missense Mutation (SNP) | VAF 13/283 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.201); called by muse, mutect2
- GALNT3 | c.274G>T p.A92S | Missense Mutation (SNP) | VAF 37/285 reads (13%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- GAN | c.1202G>C p.W401S | Missense Mutation (SNP) | VAF 39/321 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GCDH | c.226del p.Q76Rfs*66 | Frame Shift Del (DEL) | VAF 61/481 reads (13%) | called by mutect2, pindel, varscan2
- GFI1B | c.97C>A p.P33T | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2
- GFRA1 | c.451G>T p.G151W | Missense Mutation (SNP) | VAF 15/180 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); called by muse, mutect2
- GLI2 | c.3906G>T p.Q1302H (on ENST00000361492 / NM_001374353.1; = p.Q1319H on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.029); called by muse, mutect2
- GMPR | c.276C>G p.H92Q | Missense Mutation (SNP) | VAF 38/224 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GOLGA8S | c.1555G>T p.A519S | Missense Mutation (SNP) | VAF 46/532 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.229); called by muse, mutect2
- GOT2 | c.1000C>G p.P334A | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.022); called by muse, varscan2
- GPC6 | c.814A>G p.N272D | Missense Mutation (SNP) | VAF 41/269 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPHN | c.152G>T p.G51V | Missense Mutation (SNP) | VAF 15/180 reads (8%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.999); called by muse, mutect2
- GPR25 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0.028); called by muse, mutect2
- GPR42 | c.931G>T p.E311* | Nonsense Mutation (SNP) | VAF 14/110 reads (13%) | called by mutect2, varscan2
- GPR63 | c.151A>T p.M51L | Missense Mutation (SNP) | VAF 25/186 reads (13%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR65 | c.298A>T p.S100C | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); called by muse, mutect2
- GSDMC | c.565G>T p.G189C | Missense Mutation (SNP) | VAF 46/253 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.781); called by muse, varscan2
- GUCD1 | c.295-3C>T | Splice Region (SNP) | VAF 12/194 reads (6%) | called by muse, mutect2
- HAGHL | c.82G>A p.V28M | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- HAUS7 | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- HDAC9 | c.2669C>G p.A890G | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- HERC1 | c.11519G>T p.G3840V | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HERC2 | c.5889G>T p.M1963I | Missense Mutation (SNP) | VAF 20/325 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.021); called by muse, mutect2
- HES2 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 23/254 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); called by muse, mutect2
- HHIPL2 | c.1223G>C p.G408A | Missense Mutation (SNP) | VAF 51/300 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- HMCN1 | c.9957T>A p.C3319* | Nonsense Mutation (SNP) | VAF 57/360 reads (16%) | called by muse, mutect2, varscan2
- HMGXB4 | c.458G>T p.S153I | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- HMSD | c.331A>T p.K111* | Nonsense Mutation (SNP) | VAF 24/205 reads (12%) | called by muse, mutect2, varscan2
- HNRNPU | c.575C>T p.S192L | Missense Mutation (SNP) | VAF 35/218 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- HR | c.1307C>A p.P436Q | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- HS3ST5 | c.866C>A p.T289N | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- ICE1 | c.2272A>T p.R758* | Nonsense Mutation (SNP) | VAF 28/197 reads (14%) | called by muse, mutect2, varscan2
- IGF1R | c.2140G>T p.E714* | Nonsense Mutation (SNP) | VAF 30/469 reads (6%) | called by muse, mutect2
- IGHA2 | c.761G>T p.G254V | Missense Mutation (SNP) | VAF 11/216 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- IGHV4-61 | c.335C>A p.A112D | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- IGHV5-51 | c.133G>T p.G45* | Nonsense Mutation (SNP) | VAF 32/251 reads (13%) | called by muse, mutect2, varscan2
- IGLV2-23 | c.89C>A p.S30Y | Missense Mutation (SNP) | VAF 24/197 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IL13RA1 | c.837G>T p.E279D | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- IL18RAP | c.550G>T p.A184S | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- IL21R | c.1515T>A p.C505* | Nonsense Mutation (SNP) | VAF 15/188 reads (8%) | called by muse, mutect2
- INSL5 | c.295C>A p.P99T | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); called by muse, mutect2
- INSRR | c.1094A>T p.E365V | Missense Mutation (SNP) | VAF 37/225 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- IRS4 | c.3559C>T p.P1187S | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IRX2 | c.1049G>T p.G350V | Missense Mutation (SNP) | VAF 18/199 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- ITPR3 | c.4063G>T p.G1355C | Missense Mutation (SNP) | VAF 66/274 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- ITSN1 | c.4103G>T p.G1368V | Missense Mutation (SNP) | VAF 23/207 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- JAK2 | c.1104A>C p.L368F | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- KCNE4 | c.190G>T p.G64C | Missense Mutation (SNP) | VAF 21/251 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.876); called by muse, mutect2
- KCNF1 | c.1471C>G p.Q491E | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- KCNH1 | c.513C>A p.S171R | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.051); called by mutect2, varscan2
- KCNK6 | c.360G>T p.K120N | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KIAA2026 | c.1591C>A p.L531M | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- KIF18B | c.1985C>T p.S662F (on ENST00000593135 / NM_001265577.2; = p.S674F on NM_001264573.2) | Missense Mutation (SNP) | VAF 44/261 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- KIF5A | c.969G>T p.R323= | Splice Region (SNP) | VAF 27/263 reads (10%) | called by muse, mutect2
- KIR3DL2 | c.487G>T p.D163Y | Missense Mutation (SNP) | VAF 66/564 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KIRREL2 | c.25C>T p.L9F | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KLC4 | c.1321G>C p.E441Q | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.021); called by muse, mutect2
- KRT76 | c.1688G>C p.S563T | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.432); called by muse, varscan2
- KRT9 | c.346G>C p.G116R | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- LAMB1 | c.2326G>T p.D776Y | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LDB3 | c.1468T>C p.W490R | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- LEFTY2 | c.166C>A p.H56N | Missense Mutation (SNP) | VAF 18/260 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.081); called by muse, mutect2
- LMAN1L | c.492G>T p.Q164H | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- LMTK2 | c.3256G>T p.E1086* | Nonsense Mutation (SNP) | VAF 20/184 reads (11%) | called by muse, mutect2
- LPXN | c.13G>C p.D5H | Missense Mutation (SNP) | VAF 21/229 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- LRP4 | c.2369C>A p.T790K | Missense Mutation (SNP) | VAF 64/342 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LRRC23 | c.404A>T p.Y135F | Missense Mutation (SNP) | VAF 41/286 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- LRRC4C | c.1017G>C p.R339S | Missense Mutation (SNP) | VAF 22/208 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- LRRC53 | c.232C>A p.H78N | Missense Mutation (SNP) | VAF 24/344 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2
- LRRC66 | c.2504C>G p.A835G | Missense Mutation (SNP) | VAF 30/469 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.242); called by muse, mutect2
- LRRC74B | c.20G>A p.R7K | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LSAMP | c.991C>A p.L331M | Missense Mutation (SNP) | VAF 26/217 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- MACF1 | c.18892A>T p.S6298C (on ENST00000372915; = p.S4343C on NM_012090.5) | Missense Mutation (SNP) | VAF 14/367 reads (4%) | called by muse, mutect2
- MARCHF11 | c.1044G>C p.L348F | Missense Mutation (SNP) | VAF 156/540 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- MBOAT7 | c.97G>A p.G33R | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.549); called by muse, mutect2
- MED14 | c.4186A>G p.T1396A | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MEGF10 | c.1009G>T p.G337C | Missense Mutation (SNP) | VAF 77/386 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MFSD5 | c.713G>C p.G238A | Missense Mutation (SNP) | VAF 28/212 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MGAM2 | c.6077C>A p.A2026E | Missense Mutation (SNP) | VAF 33/252 reads (13%) | SIFT tolerated, low confidence (0.73); called by muse, mutect2, varscan2
- MIA3 | c.53G>T p.W18L | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- MKRN3 | c.1135G>T p.E379* | Nonsense Mutation (SNP) | VAF 26/294 reads (9%) | called by muse, mutect2
- MMD2 | c.627C>G p.I209M (on ENST00000404774 / NM_001100600.2; = p.I185M on NM_198403.4) | Missense Mutation (SNP) | VAF 53/226 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- MPO | c.1463C>A p.P488Q | Missense Mutation (SNP) | VAF 47/436 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MRC2 | c.463A>C p.S155R | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.054); called by muse, mutect2
- MROH7 | c.2656G>T p.A886S | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2
- MRTFB | c.1558A>G p.T520A | Missense Mutation (SNP) | VAF 37/266 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MSR1 | c.899-1G>C p.X300_splice | Splice Site (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- MSR1 | c.662A>G p.N221S | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.197); called by muse, mutect2
- MSTN | c.762G>T p.E254D | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- MTA1 | c.1839G>T p.R613S | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2
- MTR | c.1943G>T p.R648L | Missense Mutation (SNP) | VAF 58/435 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC16 | c.15221C>G p.S5074C | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- MUC4 | c.291G>A p.M97I | Missense Mutation (SNP) | VAF 48/188 reads (26%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MYADM | c.518C>A p.P173H | Missense Mutation (SNP) | VAF 30/236 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- MYBPC2 | c.2313C>G p.Y771* | Nonsense Mutation (SNP) | VAF 8/99 reads (8%) | called by muse, mutect2
- MYCN | c.884C>A p.T295N | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.077); called by muse, mutect2
- MYO9B | c.3892C>T p.Q1298* | Nonsense Mutation (SNP) | VAF 68/476 reads (14%) | called by muse, varscan2
- NCAM1 | c.1285G>T p.G429W (on ENST00000316851 / NM_181351.5; = p.G419W on NM_000615.7) | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NDUFS2 | c.1353A>T p.I451= | Splice Region (SNP) | VAF 48/241 reads (20%) | called by muse, mutect2, varscan2
- NETO1 | c.108G>T p.Q36H | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.423); called by muse, mutect2
- NEU4 | c.768G>T p.E256D (on ENST00000391969 / NM_001167602.3; = p.E268D on NM_080741.4) | Missense Mutation (SNP) | VAF 11/186 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.018); called by muse, mutect2
- NFKBIA | c.254A>T p.E85V | Missense Mutation (SNP) | VAF 95/414 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NFKBIA | c.253G>T p.E85* | Nonsense Mutation (SNP) | VAF 94/417 reads (23%) | called by muse, mutect2, varscan2
- NLGN1 | c.1175G>T p.G392V | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NLRP4 | c.273G>T p.E91D | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- NLRP7 | c.436T>C p.F146L | Missense Mutation (SNP) | VAF 35/340 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NLRP8 | c.2524G>C p.E842Q | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.057); called by muse, mutect2
- NNT | c.2001del p.K667Nfs*7 | Frame Shift Del (DEL) | VAF 41/158 reads (26%) | called by mutect2, pindel, varscan2
- NOC4L | c.1330C>A p.H444N | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NOL10 | c.983T>A p.L328Q | Missense Mutation (SNP) | VAF 11/149 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); called by muse, mutect2
- NOL4 | c.1108G>T p.D370Y | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- NOMO2 | c.2217G>T p.Q739H | Missense Mutation (SNP) | VAF 67/824 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2
- NOVA1 | c.1396G>T p.G466C | Missense Mutation (SNP) | VAF 30/354 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- NPBWR1 | c.489G>T p.W163C | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPC1 | c.536A>G p.K179R | Missense Mutation (SNP) | VAF 34/195 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- NRXN1 | c.1193C>A p.T398K | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NSD1 | c.2312G>T p.G771V | Missense Mutation (SNP) | VAF 71/327 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- NTNG1 | c.314T>A p.L105Q | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- NUTM2F | c.334C>G p.P112A | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- NXF3 | c.167A>G p.H56R | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NYAP2 | c.1879C>A p.P627T | Missense Mutation (SNP) | VAF 22/267 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- OR10H1 | c.398A>C p.N133T | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- OR11H1 | c.914T>A p.L305Q | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- OR2S2 | c.16G>C p.E6Q | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR2T33 | c.186C>A p.S62R | Missense Mutation (SNP) | VAF 31/304 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- OR4C5 | c.514G>C p.G172R | Missense Mutation (SNP) | VAF 32/208 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- OR4S2 | c.808G>T p.A270S | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- OR51E2 | c.611T>A p.L204Q | Missense Mutation (SNP) | VAF 48/285 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- OR51S1 | c.544C>A p.L182I | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- OR52B4 | c.795G>T p.R265S | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- OVCH1 | c.2280+1G>T p.X760_splice | Splice Site (SNP) | VAF 22/238 reads (9%) | called by muse, mutect2, varscan2
- OVOL1 | c.455G>T p.G152V | Missense Mutation (SNP) | VAF 29/194 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PADI6 | c.1125G>T p.L375F | Missense Mutation (SNP) | VAF 28/260 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.045); called by muse, mutect2
- PARP4 | c.4444G>T p.A1482S | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, varscan2
- PAX9 | c.896G>T p.G299V | Missense Mutation (SNP) | VAF 49/425 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PDCD2L | c.788A>T p.Q263L | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PIGR | c.1933G>T p.V645L | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PIK3C3 | c.2523G>C p.K841N | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- PIKFYVE | c.699G>T p.L233F | Missense Mutation (SNP) | VAF 22/336 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- PKHD1L1 | c.6556T>A p.W2186R | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PKHD1L1 | c.8011C>A p.H2671N | Missense Mutation (SNP) | VAF 32/250 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.082); called by mutect2, varscan2
- PLEKHG4B | c.581G>C p.S194T (on ENST00000283426; = p.S550T on NM_052909.5) | Missense Mutation (SNP) | VAF 94/294 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PLEKHH2 | c.1381C>T p.P461S | Missense Mutation (SNP) | VAF 29/290 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POLQ | c.1012C>T p.H338Y | Missense Mutation (SNP) | VAF 23/197 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- POM121L12 | c.215T>G p.V72G | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- POTEF | c.629T>G p.L210R | Missense Mutation (SNP) | VAF 20/298 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- POU4F2 | c.628G>T p.G210C | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); called by muse, mutect2
- POU5F1B | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 24/256 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POU5F1B | c.821G>C p.R274P | Missense Mutation (SNP) | VAF 57/526 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- PP2D1 | c.163G>T p.E55* | Nonsense Mutation (SNP) | VAF 18/291 reads (6%) | called by muse, mutect2
- PPFIA4 | c.2779A>T p.T927S (on ENST00000447715; = p.T928S on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/207 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.131); called by muse, varscan2
- PPP1R26 | c.394del p.D132Tfs*10 | Frame Shift Del (DEL) | VAF 7/37 reads (19%) | called by mutect2, pindel, varscan2
- PRDM8 | c.136C>A p.L46M | Missense Mutation (SNP) | VAF 34/267 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRKCQ | c.1590G>T p.M530I | Missense Mutation (SNP) | VAF 25/226 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PRODH2 | c.1285T>A p.C429S (on ENST00000301175; = p.C353S on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.492); called by muse, mutect2
- PSG8 | c.713A>T p.K238M | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); called by muse, mutect2
- PTCHD4 | c.715G>T p.V239L | Missense Mutation (SNP) | VAF 10/255 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.205); called by muse, mutect2
- PTPRD | c.5593A>T p.R1865* | Nonsense Mutation (SNP) | VAF 18/153 reads (12%) | called by muse, mutect2, varscan2
- PTPRR | c.1112T>A p.L371Q | Missense Mutation (SNP) | VAF 23/228 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- QRICH1 | c.820G>T p.G274C | Missense Mutation (SNP) | VAF 16/193 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- QRICH1 | c.819G>T p.Q273H | Missense Mutation (SNP) | VAF 15/190 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); called by muse, mutect2
- RBBP5 | c.874G>T p.G292W | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBM26 | c.408G>T p.R136S | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBM3 | c.201G>A p.M67I | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- RBM6 | c.658G>T p.V220L | Missense Mutation (SNP) | VAF 9/179 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- RCBTB1 | c.278-1G>C p.X93_splice | Splice Site (SNP) | VAF 6/56 reads (11%) | called by muse, mutect2
- REM1 | c.882T>A p.N294K | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.078); called by muse, varscan2
- RET | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 40/364 reads (11%) | called by muse, mutect2, varscan2
- RFPL4A | c.121G>C p.E41Q | Missense Mutation (SNP) | VAF 24/343 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- RFPL4A | c.693T>A p.N231K | Missense Mutation (SNP) | VAF 56/1179 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.973); called by muse, mutect2
- RFX8 | c.1337C>A p.P446H (on ENST00000646446; = p.P375H on NM_001145664.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/253 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- RHAG | c.898G>C p.G300R | Missense Mutation (SNP) | VAF 40/400 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RHBG | c.1313C>A p.P438H | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RIC1 | c.475A>T p.T159S | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.208); called by muse, mutect2
- RNF150 | c.738C>A p.R246= | Splice Region (SNP) | VAF 11/116 reads (9%) | called by muse, mutect2
- RNF157 | c.334A>T p.S112C | Missense Mutation (SNP) | VAF 26/193 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- RNF224 | c.373C>A p.P125T | Missense Mutation (SNP) | VAF 31/215 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- RNPC3 | c.385A>G p.K129E | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.23); called by muse, mutect2
- ROBO2 | c.2846G>C p.G949A | Missense Mutation (SNP) | VAF 24/246 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, mutect2
- RP1L1 | c.5904G>T p.E1968D | Missense Mutation (SNP) | VAF 31/291 reads (11%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- RTL9 | c.2188G>C p.G730R | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); called by muse, mutect2
- RYR2 | c.7975C>A p.Q2659K | Missense Mutation (SNP) | VAF 13/157 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.351); called by muse, mutect2
- RYR2 | c.14548T>G p.F4850V | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- S1PR4 | c.1030G>T p.A344S | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SAP130 | c.2573A>T p.D858V | Missense Mutation (SNP) | VAF 16/355 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.827); called by muse, mutect2
- SATB2 | c.634G>T p.A212S | Missense Mutation (SNP) | VAF 20/271 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2
- SEC24C | c.3054+6G>T | Splice Region (SNP) | VAF 20/223 reads (9%) | called by muse, mutect2
- SEMA5A | c.2621C>A p.A874D | Missense Mutation (SNP) | VAF 72/222 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- SEMA6A | c.2446G>A p.V816M | Missense Mutation (SNP) | VAF 49/204 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- SEMA6A | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- SEMG2 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 29/271 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SEPTIN9 | c.1625+5G>A | Splice Region (SNP) | VAF 40/254 reads (16%) | called by muse, mutect2, varscan2
- SFT2D2 | c.444G>T p.R148S | Missense Mutation (SNP) | VAF 30/237 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SFTPA2 | c.346C>T p.H116Y | Missense Mutation (SNP) | VAF 28/330 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.662); called by muse, mutect2
- SFTPB | c.857-1G>A p.X286_splice | Splice Site (SNP) | VAF 58/480 reads (12%) | called by muse, mutect2, varscan2
- SHANK1 | c.139G>T p.A47S | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SHISA9 | c.155G>T p.G52V | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SHOX2 | c.685A>T p.R229W (on ENST00000441443 / NM_006884.3; = p.R253W on NM_003030.4) | Missense Mutation (SNP) | VAF 15/157 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SIPA1L1 | c.694G>T p.D232Y | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); called by muse, mutect2
- SIRPA | c.1130G>T p.G377V | Missense Mutation (SNP) | VAF 25/252 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC13A4 | c.176C>A p.A59D | Missense Mutation (SNP) | VAF 34/240 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC1A7 | c.452T>A p.L151Q | Missense Mutation (SNP) | VAF 28/222 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC25A13 | c.1737G>A p.W579* | Nonsense Mutation (SNP) | VAF 54/398 reads (14%) | called by muse, mutect2, varscan2
- SLC4A7 | c.3028G>T p.V1010F | Missense Mutation (SNP) | VAF 21/240 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.131); called by muse, mutect2
- SLC6A4 | c.1504C>A p.L502I | Missense Mutation (SNP) | VAF 14/175 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.181); called by muse, mutect2
- SLC9A3 | c.869T>C p.V290A | Missense Mutation (SNP) | VAF 79/311 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- SLCO1B1 | c.667G>T p.G223C | Missense Mutation (SNP) | VAF 20/264 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SMAD2 | c.989G>T p.R330M | Missense Mutation (SNP) | VAF 16/265 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- SMC4 | c.1532G>T p.S511I | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); called by muse, mutect2
- SNRK | c.1195C>A p.L399I | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- SORCS1 | c.1103C>G p.P368R | Missense Mutation (SNP) | VAF 15/218 reads (7%) | SIFT tolerated (0.79); PolyPhen benign (0.174); called by muse, mutect2
- SORCS3 | c.224C>A p.A75E | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, varscan2
- SORCS3 | c.2936T>A p.V979D | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- SP140 | c.2239G>A p.E747K | Missense Mutation (SNP) | VAF 12/208 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- SPAG9 | c.215_221del p.Q72Rfs*51 | Frame Shift Del (DEL) | VAF 24/222 reads (11%) | called by mutect2, pindel, varscan2
- SPATA31D1 | c.44G>T p.G15V | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- SPIC | c.407_408del p.T136Kfs*59 | Frame Shift Del (DEL) | VAF 11/174 reads (6%) | called by muse*, mutect2
- SSU72P8 | c.133C>A p.P45T | Missense Mutation (SNP) | VAF 20/231 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SSU72P8 | c.134C>A p.P45Q | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ST6GALNAC3 | c.283G>T p.G95* | Nonsense Mutation (SNP) | VAF 20/196 reads (10%) | called by muse, mutect2, varscan2
- STRC | c.4435C>A p.Q1479K | Missense Mutation (SNP) | VAF 30/400 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- STXBP6 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SUSD1 | c.1465C>T p.P489S | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2
- SV2A | c.1107G>T p.E369D | Missense Mutation (SNP) | VAF 25/229 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- SYNE2 | c.437G>T p.C146F | Missense Mutation (SNP) | VAF 29/253 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SYNE3 | c.2147A>T p.E716V | Missense Mutation (SNP) | VAF 17/193 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); called by muse, mutect2
- SYNE3 | c.548G>T p.R183M | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); called by muse, mutect2
- TAAR2 | c.553G>T p.A185S (on ENST00000367931 / NM_001033080.1; = p.A140S on NM_014626.3) | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- TAF1L | c.3189G>T p.M1063I | Missense Mutation (SNP) | VAF 28/282 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- TATDN3 | c.98A>T p.K33M | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- TBL2 | c.757G>T p.V253L | Missense Mutation (SNP) | VAF 21/202 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2
- TBX10 | c.355C>A p.P119T | Missense Mutation (SNP) | VAF 40/254 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TENM4 | c.2079G>T p.R693S | Missense Mutation (SNP) | VAF 28/188 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- TEX26 | c.185T>A p.L62H | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- TG | c.6927G>T p.E2309D | Missense Mutation (SNP) | VAF 68/400 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- THBS1 | c.2284C>G p.Q762E | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- THSD7A | c.1269C>A p.A423= | Splice Region (SNP) | VAF 22/134 reads (16%) | called by muse, varscan2
- TIGD4 | c.754T>C p.Y252H | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TLN1 | c.6975G>T p.Q2325H | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- TMEM207 | c.175G>C p.V59L | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.005); called by muse, mutect2
- TMEM63C | c.2220+1G>T p.X740_splice | Splice Site (SNP) | VAF 27/198 reads (14%) | called by muse, varscan2
- TMPRSS13 | c.1137G>C p.W379C | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMPRSS13 | c.158G>T p.R53L | Missense Mutation (SNP) | VAF 72/455 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- TNKS1BP1 | c.1063G>T p.G355W | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, mutect2
- TNNT3 | c.652C>A p.L218M (on ENST00000397301 / NM_001367846.1; = p.L207M on NM_006757.4) | Missense Mutation (SNP) | VAF 57/410 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- TNR | c.2382G>C p.W794C | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TOGARAM2 | c.684G>T p.M228I | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, varscan2
- TOP1MT | c.1040A>G p.H347R | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TOPAZ1 | c.3091T>A p.C1031S | Missense Mutation (SNP) | VAF 11/185 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.12); called by muse, mutect2
- TPPP | c.433G>T p.E145* | Nonsense Mutation (SNP) | VAF 45/157 reads (29%) | called by muse, mutect2, varscan2
- TPR | c.6939A>T p.V2313= | Splice Region (SNP) | VAF 34/307 reads (11%) | called by muse, mutect2, varscan2
- TPRN | c.1114G>T p.V372L | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TRAPPC9 | c.2689C>A p.P897T | Missense Mutation (SNP) | VAF 45/427 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRAV12-1 | c.280C>A p.L94M | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRBV29-1 | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- TRIM58 | c.1342T>A p.F448I | Missense Mutation (SNP) | VAF 29/260 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIM7 | c.421T>A p.C141S | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- TRIO | c.8417G>T p.R2806I | Missense Mutation (SNP) | VAF 78/236 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TSHZ2 | c.1238C>A p.S413Y | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- TTC17 | c.1897G>T p.G633* | Nonsense Mutation (SNP) | VAF 27/176 reads (15%) | called by muse, mutect2, varscan2
- TXNDC5 | c.492G>T p.M164I | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- UBB | c.677G>T p.R226M | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- UQCR11 | c.51G>T p.W17C | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USH2A | c.6748C>T p.H2250Y | Missense Mutation (SNP) | VAF 36/281 reads (13%) | SIFT tolerated (0.83); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- USH2A | c.1352A>T p.N451I | Missense Mutation (SNP) | VAF 31/287 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- VRK2 | c.454del p.D152Mfs*16 | Frame Shift Del (DEL) | VAF 8/67 reads (12%) | called by mutect2, pindel
- VRK2 | c.652A>T p.S218C | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- VSX1 | c.886C>A p.H296N | Missense Mutation (SNP) | VAF 30/248 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- VWCE | c.1608G>T p.M536I | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- WDPCP | c.1195G>T p.G399W | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- XDH | c.1126T>C p.S376P | Missense Mutation (SNP) | VAF 43/394 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- XPC | c.2174G>T p.R725L | Missense Mutation (SNP) | VAF 23/183 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- ZBED8 | c.998G>T p.W333L | Missense Mutation (SNP) | VAF 45/273 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZDBF2 | c.1131G>C p.Q377H | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.009); called by muse, mutect2
- ZEB2 | c.2348C>A p.P783H | Missense Mutation (SNP) | VAF 34/333 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ZFP64 | c.218A>T p.E73V | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2
- ZGLP1 | c.195G>C p.E65D | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.407); called by muse, varscan2
- ZNF185 | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF197 | c.1168A>G p.R390G | Missense Mutation (SNP) | VAF 11/142 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); called by muse, mutect2
- ZNF200 | c.355G>C p.E119Q | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); called by muse, mutect2
- ZNF274 | c.340C>T p.L114F (on ENST00000610905; = p.L9F on NM_016324.3) | Missense Mutation (SNP) | VAF 28/200 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- ZNF37A | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.89); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF415 | c.580G>T p.G194W | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF534 | c.1201G>T p.G401C (on ENST00000332323 / NM_001143939.3; = p.G388C on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- ZNF585A | c.1135G>T p.E379* (on ENST00000292841 / NM_001288800.2; = p.E324* on NM_152655.3) | Nonsense Mutation (SNP) | VAF 17/115 reads (15%) | called by muse, mutect2, varscan2
- ZNF585B | c.1287A>T p.Q429H | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ZNF623 | c.1007A>T p.Q336L | Missense Mutation (SNP) | VAF 33/283 reads (12%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ZNF649 | c.1372G>T p.G458W | Missense Mutation (SNP) | VAF 33/257 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- ZNF677 | c.581G>T p.S194I | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- ZNF729 | c.3150T>A p.C1050* | Nonsense Mutation (SNP) | VAF 23/154 reads (15%) | called by muse, mutect2, varscan2
- ZNF729 | c.3512A>T p.Q1171L | Missense Mutation (SNP) | VAF 31/249 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- ZNF746 | c.685G>T p.G229* | Nonsense Mutation (SNP) | VAF 7/50 reads (14%) | called by muse, mutect2
- ZNF827 | c.2725A>T p.N909Y | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZZEF1 | c.3793G>T p.E1265* | Nonsense Mutation (SNP) | VAF 26/107 reads (24%) | called by muse, mutect2, varscan2
- ABHD3 | c.93G>T p.G31= | Silent (SNP) | VAF 10/160 reads (6%) | called by muse, mutect2
- ADAMTS19 | c.420G>T p.P140= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as rs957121688; called by muse, mutect2
- ADD2 | c.2079C>A p.S693= | Silent (SNP) | VAF 34/279 reads (12%) | catalogued as COSV52454236; called by muse, mutect2, varscan2
- AGL | c.510G>A p.R170= | Silent (SNP) | VAF 34/342 reads (10%) | called by muse, mutect2
- AKNAD1 | c.1002C>A p.P334= | Silent (SNP) | VAF 8/158 reads (5%) | called by muse, mutect2
- ANK1 | c.5148T>A p.A1716= | Silent (SNP) | VAF 15/109 reads (14%) | called by muse, mutect2
- ANKRD34C | c.996C>A p.A332= | Silent (SNP) | VAF 19/135 reads (14%) | called by muse, mutect2, varscan2
- ANTXRL | c.1314G>A p.G438= | Silent (SNP) | VAF 15/107 reads (14%) | catalogued as rs1554963568; called by muse, mutect2, varscan2
- APOB | c.2838T>C p.S946= | Silent (SNP) | VAF 38/436 reads (9%) | called by muse, mutect2
- ASXL2 | c.1350A>G p.Q450= | Silent (SNP) | VAF 19/189 reads (10%) | called by muse, mutect2
- ATP13A2 | c.997C>T p.L333= | Silent (SNP) | VAF 9/106 reads (8%) | called by muse, mutect2
- AXL | c.1206G>T p.L402= | Silent (SNP) | VAF 7/90 reads (8%) | called by muse, mutect2
- BACE2 | c.174C>T p.D58= | Silent (SNP) | VAF 7/81 reads (9%) | catalogued as COSV57741135; called by muse, mutect2
- BDKRB1 | c.654C>T p.I218= | Silent (SNP) | VAF 31/270 reads (11%) | catalogued as rs753420449, COSV53706260; called by muse, mutect2, varscan2
- BEAN1 | c.672C>A p.P224= (on ENST00000536005 / NM_001178020.3; = p.P115= on NM_001136106.5) | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as rs1336018847; called by muse, mutect2, varscan2
- BMPER | c.1557G>T p.V519= | Silent (SNP) | VAF 68/321 reads (21%) | catalogued as COSV51810639; called by muse, mutect2, varscan2
- BPIFA3 | c.84C>A p.G28= | Silent (SNP) | VAF 19/196 reads (10%) | called by muse, mutect2
- C5AR1 | c.849C>T p.S283= | Silent (SNP) | VAF 16/116 reads (14%) | called by muse, mutect2, varscan2
- CEACAM20 | c.90C>G p.A30= | Silent (SNP) | VAF 9/99 reads (9%) | called by muse, mutect2
- CFAP46 | c.7914C>A p.G2638= | Silent (SNP) | VAF 12/103 reads (12%) | called by muse, mutect2, varscan2
- CHD5 | c.2271C>A p.P757= | Silent (SNP) | VAF 8/62 reads (13%) | called by muse, mutect2
- CHODL | c.480C>A p.P160= | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as rs767282571, COSV100166604; called by mutect2, varscan2
- CILP2 | c.2754A>T p.T918= | Silent (SNP) | VAF 18/128 reads (14%) | called by muse, mutect2, varscan2
- CKAP4 | c.348G>T p.L116= | Silent (SNP) | VAF 11/199 reads (6%) | called by muse, mutect2
- CLCA4 | c.330C>A p.L110= | Silent (SNP) | VAF 10/136 reads (7%) | catalogued as rs1343178324, COSV55367460, COSV55368999; called by muse, mutect2
- CLEC4E | c.579T>C p.N193= | Silent (SNP) | VAF 20/171 reads (12%) | called by muse, varscan2
- CMYA5 | c.8172G>T p.L2724= | Silent (SNP) | VAF 28/199 reads (14%) | called by muse, mutect2, varscan2
- COL6A2 | c.558G>T p.R186= | Silent (SNP) | VAF 21/134 reads (16%) | called by muse, mutect2, varscan2
- CR1 | c.3696C>T p.L1232= | Silent (SNP) | VAF 31/184 reads (17%) | catalogued as COSV100888124; called by muse, mutect2, varscan2
- CRP | c.550C>T p.L184= | Silent (SNP) | VAF 22/253 reads (9%) | called by muse, mutect2
- CSF2RB | c.372C>A p.T124= | Silent (SNP) | VAF 45/169 reads (27%) | called by muse, mutect2, varscan2
- CTNND2 | c.2230C>T p.L744= | Silent (SNP) | VAF 38/362 reads (10%) | catalogued as rs752031679; called by muse, mutect2, varscan2
- CYP2B6 | c.882G>T p.S294= | Silent (SNP) | VAF 42/450 reads (9%) | called by muse, mutect2
- DDR2 | c.1122T>A p.S374= | Silent (SNP) | VAF 50/411 reads (12%) | called by muse, mutect2, varscan2
- DKK2 | c.555A>G p.R185= | Silent (SNP) | VAF 10/156 reads (6%) | called by muse, mutect2
- DLG5 | c.4365C>T p.G1455= | Silent (SNP) | VAF 14/160 reads (9%) | called by muse, mutect2
- DNAH14 | c.4374A>G p.R1458= (on ENST00000445597; = p.R1863= on NM_001367479.1) | Silent (SNP) | VAF 16/174 reads (9%) | called by muse, mutect2
- DNAH3 | c.4113G>A p.L1371= | Silent (SNP) | VAF 47/382 reads (12%) | called by muse, mutect2, varscan2
- DOCK10 | c.5862G>T p.P1954= | Silent (SNP) | VAF 31/295 reads (11%) | called by muse, mutect2, varscan2
- DOCK2 | c.4092C>A p.R1364= | Silent (SNP) | VAF 21/116 reads (18%) | called by muse, mutect2, varscan2
- DROSHA | c.3984G>T p.A1328= | Silent (SNP) | VAF 48/149 reads (32%) | called by muse, mutect2, varscan2
- DST | c.2646T>A p.S882= (on ENST00000361203 / NM_001374722.1; = p.S556= on NM_001723.6) | Silent (SNP) | VAF 31/262 reads (12%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.4794G>A p.Q1598= | Silent (SNP) | VAF 27/232 reads (12%) | called by muse, mutect2, varscan2
- DYNLRB1 | c.63C>T p.I21= | Silent (SNP) | VAF 22/210 reads (10%) | catalogued as rs111421208; called by muse, mutect2, varscan2
- EIF2AK1 | c.1035C>G p.L345= | Silent (SNP) | VAF 35/327 reads (11%) | catalogued as rs1182155840; called by muse, mutect2, varscan2
- EIF3B | c.2271C>T p.F757= | Silent (SNP) | VAF 50/159 reads (31%) | called by muse, mutect2, varscan2
- EML6 | c.4182A>T p.A1394= | Silent (SNP) | VAF 11/159 reads (7%) | called by muse, mutect2
- EPHA10 | c.774C>G p.A258= | Silent (SNP) | VAF 8/136 reads (6%) | called by muse, mutect2
- EPPK1 | c.2358G>T p.V786= | Silent (SNP) | VAF 38/195 reads (19%) | called by muse, mutect2, varscan2
- F2R | c.492C>T p.S164= | Silent (SNP) | VAF 44/281 reads (16%) | catalogued as rs746222469; called by muse, mutect2, varscan2
- FAM205A | c.642C>A p.L214= | Silent (SNP) | VAF 11/157 reads (7%) | catalogued as COSV101113054; called by muse, mutect2
- FEM1B | c.639A>T p.I213= | Silent (SNP) | VAF 14/125 reads (11%) | called by muse, mutect2, varscan2
- FLNC | c.4644C>A p.G1548= | Silent (SNP) | VAF 30/334 reads (9%) | catalogued as rs762001332; called by muse, mutect2
- FOXK2 | c.849G>T p.G283= | Silent (SNP) | VAF 8/107 reads (7%) | called by muse, mutect2
- GABRG1 | c.348C>A p.A116= | Silent (SNP) | VAF 56/154 reads (36%) | called by muse, mutect2, varscan2
- GALNT16 | c.105C>T p.S35= | Silent (SNP) | VAF 31/309 reads (10%) | called by muse, mutect2
- GALNT7 | c.666C>T p.T222= | Silent (SNP) | VAF 18/198 reads (9%) | catalogued as rs1468331671; called by muse, mutect2
- GAP43 | c.465G>A p.K155= | Silent (SNP) | VAF 21/110 reads (19%) | catalogued as COSV59346154; called by muse, mutect2, varscan2
- GATA4 | c.601C>A p.R201= | Silent (SNP) | VAF 11/84 reads (13%) | called by muse, mutect2, varscan2
- GPR22 | c.867T>C p.S289= | Silent (SNP) | VAF 16/161 reads (10%) | catalogued as rs779853997; called by muse, mutect2, varscan2
- GRAMD1A | c.1272G>T p.T424= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV58767198; called by mutect2, varscan2
- HPD | c.663T>C p.Y221= | Silent (SNP) | VAF 43/425 reads (10%) | catalogued as rs752500607; called by muse, mutect2, varscan2
- HS3ST5 | c.867C>A p.T289= | Silent (SNP) | VAF 18/158 reads (11%) | called by muse, varscan2
- ICA1 | c.492G>T p.T164= | Silent (SNP) | VAF 36/434 reads (8%) | catalogued as COSV104377038, COSV99655591; called by muse, mutect2
- IGHV1-24 | c.108A>T p.S36= | Silent (SNP) | VAF 33/305 reads (11%) | called by muse, mutect2, varscan2
- IGHV1-58 | c.177T>A p.A59= | Silent (SNP) | VAF 22/356 reads (6%) | called by muse, mutect2
- IGHV4-61 | c.336C>A p.A112= | Silent (SNP) | VAF 12/184 reads (7%) | called by muse, mutect2
- IGSF10 | c.2760C>A p.P920= | Silent (SNP) | VAF 40/258 reads (16%) | called by muse, mutect2, varscan2
- IKZF1 | c.637C>A p.R213= | Silent (SNP) | VAF 13/178 reads (7%) | catalogued as COSV58783232; called by muse, mutect2
- IQCF5 | c.54C>A p.I18= | Silent (SNP) | VAF 14/127 reads (11%) | called by muse, mutect2, varscan2
- IRX1 | c.399C>T p.N133= | Silent (SNP) | VAF 38/424 reads (9%) | catalogued as COSV57361024; called by muse, mutect2
- KHDC1L | c.126G>T p.T42= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV64893413; called by muse, mutect2, varscan2
- KRT1 | c.228C>T p.I76= | Silent (SNP) | VAF 22/460 reads (5%) | called by muse, mutect2
- KRT6C | c.573G>T p.L191= | Silent (SNP) | VAF 40/372 reads (11%) | catalogued as COSV99360090; called by muse, mutect2, varscan2
- KRTAP21-1 | c.225C>T p.C75= | Silent (SNP) | VAF 33/332 reads (10%) | catalogued as COSV100624884; called by muse, mutect2, varscan2
- LEMD2 | c.1140G>C p.V380= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs1204569848; called by muse, varscan2
- LILRB2 | c.1767C>A p.P589= | Silent (SNP) | VAF 38/265 reads (14%) | called by muse, mutect2, varscan2
- LIPE | c.3009C>T p.L1003= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as rs1236533581; called by muse, mutect2, varscan2
- LTN1 | c.3051C>G p.V1017= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV100798131; called by muse, mutect2
- MED13L | c.6108C>T p.D2036= | Silent (SNP) | VAF 30/358 reads (8%) | catalogued as rs541206959; called by muse, mutect2
- MID1 | c.357C>T p.C119= | Silent (SNP) | VAF 15/75 reads (20%) | called by muse, mutect2, varscan2
- MTBP | c.1188A>G p.G396= | Silent (SNP) | VAF 13/129 reads (10%) | called by muse, mutect2, varscan2
- MUC6 | c.1821C>T p.A607= | Silent (SNP) | VAF 10/136 reads (7%) | called by muse, mutect2
- MYL7 | c.201G>C p.V67= | Silent (SNP) | VAF 10/124 reads (8%) | called by muse, mutect2
- MYO18B | c.7131G>C p.S2377= | Silent (SNP) | VAF 13/148 reads (9%) | catalogued as COSV59133324; called by muse, mutect2
- MYOF | c.3801A>C p.A1267= | Silent (SNP) | VAF 13/110 reads (12%) | called by muse, mutect2
- NCAPH | c.547C>T p.L183= | Silent (SNP) | VAF 12/120 reads (10%) | called by muse, mutect2
- NF1 | c.591A>T p.T197= | Silent (SNP) | VAF 30/184 reads (16%) | called by muse, mutect2, varscan2
- NF1 | c.7257G>T p.L2419= (on ENST00000358273 / NM_001042492.3; = p.L2398= on NM_000267.3) | Silent (SNP) | VAF 31/211 reads (15%) | called by muse, varscan2
- NID1 | c.2013C>A p.P671= | Silent (SNP) | VAF 33/208 reads (16%) | called by muse, mutect2, varscan2
- OGDHL | c.1536C>T p.L512= | Silent (SNP) | VAF 15/247 reads (6%) | catalogued as rs997298253, COSV65102378; called by muse, mutect2
- OR2C3 | c.174A>T p.T58= | Silent (SNP) | VAF 33/279 reads (12%) | called by muse, mutect2, varscan2
- OR2T34 | c.753C>A p.I251= | Silent (SNP) | VAF 15/142 reads (11%) | catalogued as COSV60901885; called by muse, mutect2, varscan2
- OR6Q1 | c.75A>T p.A25= | Silent (SNP) | VAF 21/150 reads (14%) | called by muse, mutect2, varscan2
- OTOG | c.6279C>A p.L2093= | Silent (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- PARS2 | c.171C>A p.L57= | Silent (SNP) | VAF 7/88 reads (8%) | called by muse, mutect2
- PCDHA1 | c.2301C>A p.T767= | Silent (SNP) | VAF 15/153 reads (10%) | called by muse, mutect2, varscan2
- PCDHGB7 | c.1434C>T p.D478= | Silent (SNP) | VAF 45/209 reads (22%) | catalogued as COSV53992806; called by muse, mutect2, varscan2
- PCED1B | c.1083A>G p.S361= | Silent (SNP) | VAF 18/322 reads (6%) | catalogued as rs959988900; called by muse, mutect2
- PCLO | c.5988A>G p.S1996= | Silent (SNP) | VAF 9/180 reads (5%) | catalogued as rs1283769008; called by muse, mutect2
- PFKL | c.132G>T p.V44= | Silent (SNP) | VAF 19/193 reads (10%) | catalogued as COSV100827220; called by muse, mutect2, varscan2
- PHF12 | c.1314G>T p.A438= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as COSV52021542; called by muse, mutect2
- PIGH | c.114G>T p.L38= | Silent (SNP) | VAF 19/188 reads (10%) | catalogued as rs1367725647; called by muse, mutect2, varscan2
- PIGR | c.1932G>T p.L644= | Silent (SNP) | VAF 18/137 reads (13%) | called by muse, mutect2, varscan2
- PLCB4 | c.2895G>T p.V965= | Silent (SNP) | VAF 25/189 reads (13%) | catalogued as COSV53819033; called by muse, mutect2, varscan2
- POU2AF1 | c.141T>A p.P47= | Silent (SNP) | VAF 35/287 reads (12%) | called by muse, mutect2, varscan2
- PRR16 | c.231G>A p.T77= (on ENST00000407149 / NM_001300783.2; = p.T54= on NM_016644.2) | Silent (SNP) | VAF 32/136 reads (24%) | catalogued as rs267600323; called by muse, mutect2, varscan2
- PRR23A | c.216C>A p.P72= | Silent (SNP) | VAF 17/106 reads (16%) | called by muse, mutect2, varscan2
- PSG3 | c.903G>A p.T301= | Silent (SNP) | VAF 28/286 reads (10%) | catalogued as rs764331640, COSV59503120, COSV59507174; called by muse, mutect2, varscan2
- PXDNL | c.2505C>A p.V835= | Silent (SNP) | VAF 24/252 reads (10%) | catalogued as rs1226711194; called by muse, mutect2
- PYGL | c.2028G>C p.G676= | Silent (SNP) | VAF 24/328 reads (7%) | called by muse, mutect2
- PYGL | c.1128C>A p.T376= | Silent (SNP) | VAF 30/190 reads (16%) | called by muse, mutect2, varscan2
- QPRT | c.360T>G p.A120= | Silent (SNP) | VAF 33/156 reads (21%) | called by muse, mutect2, varscan2
- RELN | c.210G>A p.P70= | Silent (SNP) | VAF 17/213 reads (8%) | called by muse, mutect2
- REST | c.1674G>A p.V558= | Silent (SNP) | VAF 78/385 reads (20%) | catalogued as rs775670611; called by muse, mutect2, varscan2
- ROCK1 | c.2751G>C p.T917= | Silent (SNP) | VAF 28/159 reads (18%) | catalogued as COSV67695765; called by muse, mutect2, varscan2
- RPSA | c.663A>T p.A221= | Silent (SNP) | VAF 14/292 reads (5%) | called by muse, mutect2
- RPTOR | c.921G>T p.T307= | Silent (SNP) | VAF 36/215 reads (17%) | catalogued as COSV60808774; called by muse, mutect2, varscan2
- RSPO1 | c.108G>A p.G36= | Silent (SNP) | VAF 23/175 reads (13%) | called by muse, mutect2, varscan2
- SCN2A | c.5691G>A p.T1897= | Silent (SNP) | VAF 42/373 reads (11%) | catalogued as COSV51842270, COSV51847205, COSV99333456; called by muse, mutect2, varscan2
- SCN5A | c.1701G>C p.L567= | Silent (SNP) | VAF 15/197 reads (8%) | called by muse, mutect2
- SDK2 | c.1065C>A p.T355= | Silent (SNP) | VAF 16/140 reads (11%) | catalogued as rs937364517, COSV101167692; called by muse, mutect2, varscan2
- SEMA5A | c.1836G>T p.G612= | Silent (SNP) | VAF 90/284 reads (32%) | called by muse, mutect2, varscan2
- SH3TC2 | c.183C>A p.R61= | Silent (SNP) | VAF 83/373 reads (22%) | called by muse, mutect2, varscan2
- SLC10A7 | c.114A>T p.P38= | Silent (SNP) | VAF 8/76 reads (11%) | called by muse, mutect2, varscan2
- SLC16A11 | c.777C>T p.F259= (on ENST00000308009; = p.F235= on NM_153357.3) | Silent (SNP) | VAF 25/144 reads (17%) | called by muse, mutect2, varscan2
- SLC39A12 | c.1218C>T p.G406= | Silent (SNP) | VAF 18/236 reads (8%) | catalogued as rs1159845860, COSV101069913; called by muse, mutect2
- SLC41A1 | c.162G>T p.R54= | Silent (SNP) | VAF 33/262 reads (13%) | called by muse, mutect2, varscan2
- SLC4A7 | c.1422A>T p.P474= | Silent (SNP) | VAF 17/151 reads (11%) | called by muse, mutect2, varscan2
- SLC6A15 | c.1152T>C p.I384= | Silent (SNP) | VAF 13/100 reads (13%) | catalogued as rs772461184; called by muse, mutect2, varscan2
- SLC7A4 | c.1449C>T p.G483= | Silent (SNP) | VAF 38/165 reads (23%) | catalogued as rs749829393; called by muse, mutect2, varscan2
- SLIT3 | c.2757C>T p.A919= | Silent (SNP) | VAF 35/234 reads (15%) | catalogued as rs1160514263; called by muse, mutect2, varscan2
- SLX4 | c.804G>T p.V268= | Silent (SNP) | VAF 22/184 reads (12%) | called by muse, mutect2, varscan2
- SSTR4 | c.475C>A p.R159= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as rs1449409868, COSV104369580; called by muse, mutect2, varscan2
- STX19 | c.423C>T p.F141= | Silent (SNP) | VAF 9/157 reads (6%) | catalogued as rs1415635215; called by muse, mutect2
- TECPR1 | c.561G>C p.L187= | Silent (SNP) | VAF 12/126 reads (10%) | called by muse, mutect2
- TENT4A | c.1014A>T p.P338= | Silent (SNP) | VAF 16/198 reads (8%) | called by muse, mutect2
- TEX51 | c.396A>T p.T132= (on ENST00000643416; = p.T108= on NM_001322244.2) | Silent (SNP) | VAF 21/240 reads (9%) | called by muse, mutect2
- TIGD2 | c.879C>T p.F293= | Silent (SNP) | VAF 16/140 reads (11%) | catalogued as COSV57647802; called by muse, mutect2, varscan2
- TMEM121B | c.840G>T p.S280= | Silent (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2, varscan2
- TNS2 | c.1140C>T p.L380= (on ENST00000314250 / NM_170754.4; = p.L390= on NM_015319.2) | Silent (SNP) | VAF 26/216 reads (12%) | catalogued as rs1372981603; called by muse, mutect2, varscan2
- TONSL | c.2307G>T p.V769= | Silent (SNP) | VAF 9/78 reads (12%) | called by muse, mutect2, varscan2
- TRIM62 | c.414G>A p.E138= | Silent (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2, varscan2
- TSHZ2 | c.1239C>A p.S413= | Silent (SNP) | VAF 11/97 reads (11%) | called by muse, mutect2
- TSSK1B | c.909C>T p.G303= | Silent (SNP) | VAF 27/116 reads (23%) | catalogued as rs1318711022; called by muse, mutect2, varscan2
- UROC1 | c.360G>A p.Q120= | Silent (SNP) | VAF 16/240 reads (7%) | catalogued as COSV52036626; called by muse, mutect2
- WDTC1 | c.1734G>T p.G578= (on ENST00000319394 / NM_001276252.2; = p.G577= on NM_015023.5) | Silent (SNP) | VAF 32/171 reads (19%) | called by muse, mutect2, varscan2
- ZFP64 | c.45G>T p.S15= | Silent (SNP) | VAF 18/230 reads (8%) | called by muse, mutect2
- ZFYVE9 | c.2169A>T p.A723= | Silent (SNP) | VAF 8/67 reads (12%) | called by muse, mutect2
- ZNF106 | c.786A>G p.L262= | Silent (SNP) | VAF 18/199 reads (9%) | catalogued as rs1212847274; called by muse, mutect2
- ZNF469 | c.7444T>C p.L2482= (on ENST00000437464; = p.L2510= on NM_001367624.2) | Silent (SNP) | VAF 39/250 reads (16%) | called by muse, mutect2, varscan2
- ZNF573 | c.1686C>A p.T562= (on ENST00000536220 / NM_001172692.1; = p.T504= on NM_152360.3) | Silent (SNP) | VAF 11/108 reads (10%) | called by muse, mutect2, varscan2
- ZRANB3 | c.174T>A p.A58= | Silent (SNP) | VAF 9/88 reads (10%) | called by muse, mutect2, varscan2
- AC004947.2 | chr7:26537008 A>G | 5'Flank (SNP) | VAF 5/57 reads (9%) | called by muse, mutect2
- AC012485.1 | n.254A>T | RNA (SNP) | VAF 28/282 reads (10%) | called by muse, varscan2
- AC055876.1 | n.458G>T | RNA (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2, varscan2
- ADCYAP1 | chr18:904838 C>A | 5'Flank (SNP) | VAF 20/97 reads (21%) | called by muse, mutect2, varscan2
- AGPAT4 | c.348+5111G>T | Intron (SNP) | VAF 11/116 reads (9%) | called by muse, mutect2
- ALDH1L1 | c.1983-266C>A | Intron (SNP) | VAF 10/102 reads (10%) | called by muse, mutect2
- AMPH | c.1183-1262C>A | Intron (SNP) | VAF 36/170 reads (21%) | called by muse, mutect2, varscan2
- ANK1 | c.5619+45C>T | Intron (SNP) | VAF 12/255 reads (5%) | called by muse, mutect2
84 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 84 other) are not listed here.
